TCGA case TCGA-08-0358 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: UCSF. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ec504558-e96a-44e9-835a-7b12680681ed

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 50 years; Vital status: Dead; Days to death: 678 days (1.9 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 50.3 years (18,383 days); Year of diagnosis: 2005; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Erlotinib Hydrochloride; Treatment intent type: Adjuvant; Days to treatment start: 33 days; Days to treatment end: 75 days; Treatment dose: 150 mg/day.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 33 days; Days to treatment end: 75 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 33 days; Days to treatment end: 75 days; Number of cycles: 1; Treatment dose: 150 mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Erlotinib Hydrochloride; Treatment intent type: Adjuvant; Days to treatment start: 91 days; Days to treatment end: 264 days; Treatment dose: 200 mg/day.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 91 days; Days to treatment end: 264 days; Number of cycles: 6; Treatment dose: 200 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Cintredekin Besudotox; Initial disease status: Progressive Disease; Days to treatment start: 288 days; Days to treatment end: 293 days; Treatment dose: 36 mg.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Vitespen; Initial disease status: Progressive Disease; Days to treatment start: 341 days; Days to treatment end: 467 days (1.3 years); Treatment dose: 0 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Initial disease status: Progressive Disease; Days to treatment start: 491 days (1.3 years); Days to treatment end: 548 days (1.5 years); Number of cycles: 1; Treatment dose: 220 mg; Route of administration: Oral.
2. Recurrence of diagnosis 1 (Glioblastoma). Age at diagnosis: 51.1 years (18,647 days); Days to diagnosis: 264 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 286 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS; Radiation Therapy, NOS, for recurrent disease.

Follow-up (5 entries)
- Day 264 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 264 days.
- Days to follow up: 594 days (1.6 years); Disease response: With Tumor.
- Days to follow up: 678 days (1.9 years); Disease response: With Tumor.
- Karnofsky performance status: 80; Timepoint: Prior to Adjuvant Therapy.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-08-0358-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.8; Intermediate dimension: 0.8; Shortest dimension: 0.8.
  Slide TCGA-08-0358-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 5.
  Slide TCGA-08-0358-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-08-0358-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-08-0358-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Pre-Adjuvant Therapy.
- Drug treatment 1: Pharmaceutical therapy drug name: Ccnu; Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Pharmaceutical therapy drug name: IL-13 with Pseudomonas Exotoxin; Therapy regimen: Progression.
- Drug treatment 3: Pharmaceutical therapy drug name: Temodor.
- Drug treatment 4: Pharmaceutical therapy drug name: HSPPC-96 Vaccine; Therapy regimen: Progression.
- Drug treatment 6: Pharmaceutical therapy drug name: Tarceva.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 678 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 678 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 264 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-08-0358-01): tumor purity 0.95, ploidy 1.97, whole-genome doublings 0 (call status: snp_call).
